Somatic mutation profile of tumor specimen MMRF_1290_1_BM_CD138pos (aliquot MMRF_1290_1_BM_CD138pos_T2_KHS5U_L13425) from MMRF case MMRF_1290, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,439 days).
Specimen MMRF_1290_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a408170a-6060-4562-8621-97582fee2338.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1290_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1290_1_PB_Whole_C1_KHS5U_L13426; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3891e5e0-f9ad-4cf5-bcb5-3c484129d261

The open-access MAF lists 2,650 somatic variants for this specimen: 938 protein-altering or splice-affecting, 384 silent, 1,328 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 803, 3'UTR 694, Silent 384, Intron 380, 5'UTR 120, Nonsense Mutation 92, 3'Flank 54, 5'Flank 54, RNA 26, Splice Region 20, Splice Site 13, Frame Shift Ins 5.

Variants (750 of 2,650; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs771937610, CM031630, CM940129, COSV61689902; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 213/515 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SDHAF2 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 90/308 reads (29%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV57098949, COSV57100559; called by muse, mutect2, varscan2
- TPM1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs104894505, CM014116, COSV104385526, COSV51259749; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV55588275; called by muse, mutect2, varscan2
- ABCB5 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1318774223, COSV51712789; called by muse, mutect2, varscan2
- ABR | c.1963C>T p.R655W (on ENST00000302538 / NM_021962.5; = p.R618W on NM_001092.5) | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs776045570, COSV99348857; called by muse, mutect2, varscan2
- ACHE | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.024); catalogued as rs763331269; called by muse, mutect2, varscan2
- ADAMTS3 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342330492; called by muse, mutect2, varscan2
- ADAMTS9 | c.4472G>T p.R1491I | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADGRE1 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 47/233 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.855); catalogued as COSV51673833; called by muse, mutect2, varscan2
- ADH6 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1397954670; called by muse, mutect2, varscan2
- ALCAM | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.125); catalogued as rs781270007; called by muse, mutect2, varscan2
- ALG13 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52637920; called by muse, mutect2, varscan2
- ALG13 | c.1770C>G p.F590L | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as rs778820594, COSV52637443; called by muse, mutect2, varscan2
- ALMS1 | c.12463-1G>A p.X4155_splice | Splice Site (SNP) | VAF 103/246 reads (42%) | catalogued as COSV52524883; called by muse, mutect2, varscan2
- ALS2CL | c.2814G>A p.M938I | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs764697064, COSV100014591; called by muse, mutect2, varscan2
- AMHR2 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 207/427 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV99143012; called by muse, mutect2, varscan2
- ANK2 | c.7567G>A p.E2523K | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52149446, COSV52164372; called by muse, mutect2, varscan2
- ANK3 | c.5710G>A p.D1904N | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55088933; called by muse, mutect2, varscan2
- ANKRD11 | c.1576C>G p.H526D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV56363032; called by muse, mutect2, varscan2
- ANKRD28 | c.2425G>A p.D809N | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV67519377; called by muse, mutect2, varscan2
- ANKRD54 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs770688448; called by muse, mutect2, varscan2
- ANP32A | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 113/495 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1012536396; called by muse, mutect2, varscan2
- ARC | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 91/200 reads (46%) | catalogued as COSV63077981; called by muse, mutect2, varscan2
- ARHGDIA | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 158/553 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53907258; called by muse, mutect2, varscan2
- ARHGEF12 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs768635441; called by muse, mutect2, varscan2
- ARMC10 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780024423; called by muse, mutect2, varscan2
- ARMC9 | c.1523C>G p.S508W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs537669037, COSV100589641, COSV63022614; called by muse, mutect2, varscan2
- ASB10 | c.739G>A p.E247K (on ENST00000420175 / NM_001142459.2; = p.E232K on NM_080871.4) | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs764009407, COSV51994203; called by muse, mutect2, varscan2
- ASB4 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV57946934; called by muse, mutect2, varscan2
- ATM | c.1939G>C p.E647Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV99588929; called by muse, mutect2, varscan2
- ATP1A3 | c.1276C>T p.H426Y (on ENST00000545399 / NM_001256214.2; = p.H413Y on NM_152296.5) | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs781823248; called by muse, varscan2
- ATP2A1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs778514898, COSV63920049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP5F1B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56261245; called by muse, varscan2
- ATP6V1D | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs773197310, COSV53599326; called by muse, mutect2, varscan2
- ATXN1L | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs1247129367; called by muse, mutect2, varscan2
- BAIAP2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs115451635; called by muse, mutect2, varscan2
- BARD1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV53617881, COSV99038470; called by muse, mutect2, varscan2
- BBS2 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 91/207 reads (44%) | catalogued as COSV99802133; called by muse, mutect2, varscan2
- BCAM | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs1008385792, COSV54304763; called by muse, mutect2, varscan2
- BECN1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59312461; called by muse, mutect2, varscan2
- BHLHE22 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.352); catalogued as COSV58861327, COSV58863066; called by muse, mutect2, varscan2
- BRCA2 | c.4792C>T p.L1598F | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV66460382; called by muse, mutect2, varscan2
- BRINP2 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64177685; called by muse, mutect2, varscan2
- BRINP3 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 114/230 reads (50%) | catalogued as rs865971143; called by muse, mutect2, varscan2
- CAAP1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.482); catalogued as rs756203660; called by muse, mutect2, varscan2
- CACNA2D4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV54950654; called by muse, mutect2, varscan2
- CAPN9 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs766849862, COSV55236504; called by muse, mutect2, varscan2
- CASKIN1 | c.3251C>T p.S1084L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1489143555; called by muse, mutect2, varscan2
- CAVIN3 | c.581C>G p.S194W | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58269136, COSV58269396; called by muse, varscan2
- CCDC141 | c.2101C>A p.L701I | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV55371086; called by muse, mutect2, varscan2
- CCDC18 | c.1616C>G p.S539C (on ENST00000343253 / NM_001306076.1; = p.S540C on NM_206886.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs756252757; called by muse, mutect2, varscan2
- CCDC68 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV61603359; called by muse, mutect2, varscan2
- CCDC92 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1470526730, COSV53019889; called by muse, mutect2, varscan2
- CCER1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1304055911, COSV62646111; called by muse, mutect2, varscan2
- CCNA2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs1289428016; called by muse, mutect2, varscan2
- CD200R1 | c.91G>A p.E31K (on ENST00000471858 / NM_170780.3; = p.E54K on NM_138806.4) | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0.204); catalogued as COSV55600207; called by muse, mutect2, varscan2
- CDC42BPB | c.954G>C p.Q318H | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100775417; called by muse, mutect2, varscan2
- CDC45 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 98/216 reads (45%) | catalogued as COSV54248428; called by muse, mutect2, varscan2
- CDH7 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59885113; called by muse, mutect2, varscan2
- CDK19 | c.1426C>G p.Q476E | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as rs1440180529; called by muse, mutect2, varscan2
- CDK8 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 137/245 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as COSV67420868, COSV67422355; called by muse, mutect2, varscan2
- CEMIP | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 90/263 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as rs1313251147; called by muse, mutect2, varscan2
- CEP128 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53674990; called by muse, mutect2, varscan2
- CEP350 | c.6110C>G p.S2037C | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1182014149, COSV62606206; called by muse, mutect2, varscan2
- CFAP47 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99935359; called by muse, mutect2, varscan2
- CGAS | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1554146180; called by muse, mutect2, varscan2
- CHDH | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV59459120; called by muse, mutect2, varscan2
- CIPC | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs769078546, COSV62376737; called by muse, mutect2, varscan2
- CNDP1 | c.902C>G p.P301R | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1460858008, COSV62594791; called by muse, mutect2, varscan2
- CNTNAP2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.105); catalogued as COSV100672543; called by muse, mutect2, varscan2
- COMTD1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs767641579; called by muse, mutect2, varscan2
- CPNE5 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769191832; called by muse, mutect2, varscan2
- CR1 | c.5815G>A p.E1939K | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV100887573; called by muse, mutect2, varscan2
- CTSA | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs776143304; called by muse, mutect2, varscan2
- CUZD1 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59027930; called by muse, mutect2, varscan2
- CYP2C9 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV53250187; called by muse, mutect2
- CYP4F22 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 183/638 reads (29%) | catalogued as rs377609523; called by muse, mutect2, varscan2
- DBF4B | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 130/352 reads (37%) | catalogued as COSV100154321; called by muse, varscan2
- DCHS1 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778093381, COSV55033999, COSV55034357; called by muse, mutect2, varscan2
- DDOST | c.172G>A p.E58K (on ENST00000415136; = p.E41K on NM_005216.5) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1235002415; called by muse, mutect2, varscan2
- DDX3X | c.596A>C p.Y199S (on ENST00000399959; = p.Y200S on NM_001356.5) | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863123; called by muse, varscan2
- DDX3X | c.759G>A p.M253I (on ENST00000399959; = p.M254I on NM_001356.5) | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV67864516; called by muse, mutect2, varscan2
- DGKK | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 92/203 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101052913, COSV101052977; called by muse, mutect2, varscan2
- DHX15 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.041); catalogued as COSV61028551; called by muse, mutect2, varscan2
- DIPK2A | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as rs1241525570, COSV59856713, COSV59856830; called by muse, mutect2, varscan2
- DLC1 | c.3415G>A p.E1139K (on ENST00000276297 / NM_001348081.2; = p.E702K on NM_006094.5) | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs201909353; called by muse, mutect2, varscan2
- DLG4 | c.874C>G p.R292G (on ENST00000399506 / NM_001321075.3; = p.R335G on NM_001365.4) | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV100263680, COSV57241207; called by muse, mutect2, varscan2
- DNAAF1 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773443425; called by muse, mutect2, varscan2
- DNAH2 | c.10576G>C p.E3526Q | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66719650; called by muse, mutect2, varscan2
- DNASE1 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 124/266 reads (47%) | catalogued as rs753840602; called by muse, mutect2, varscan2
- DNTT | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as COSV64522915, COSV64523763; called by muse, mutect2, varscan2
- DOK5 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV104391364; called by muse, mutect2, varscan2
- DPP7 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as rs1350078316; called by muse, mutect2, varscan2
- DPP8 | c.928G>C p.E310Q (on ENST00000341861 / NM_001320875.2; = p.E294Q on NM_017743.6) | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV55681515; called by muse, varscan2
- DRD2 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.299); catalogued as COSV100670029; called by muse, mutect2, varscan2
- DSCAM | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV101261823; called by muse, mutect2, varscan2
- DSCAM | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV68028085; called by muse, mutect2, varscan2
- DSCAML1 | c.4246G>A p.E1416K (on ENST00000321322; = p.E1356K on NM_020693.4) | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1407000587; called by muse, mutect2
- DUOX2 | c.3284C>G p.S1095C | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as rs777375808; called by muse, mutect2, varscan2
- EDIL3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV56888905; called by muse, mutect2, varscan2
- EIF5B | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV56813083; called by muse, mutect2, varscan2
- ELAVL3 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 115/533 reads (22%) | catalogued as COSV63645620; called by muse, mutect2, varscan2
- ELMO1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 109/412 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.516); catalogued as COSV100164480; called by muse, mutect2, varscan2
- EPHB3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.056); catalogued as COSV100383155; called by muse, mutect2, varscan2
- ERI3 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs779624686; called by muse, mutect2, varscan2
- ERICH5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs1478824863; called by muse, mutect2, varscan2
- ERP27 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56764094; called by muse, mutect2, varscan2
- ETV3 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.205); catalogued as rs545598508; called by muse, mutect2, varscan2
- EVPL | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs1393655341; called by muse, mutect2, varscan2
- EXOC3L1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145550510, COSV52047561; called by muse, mutect2, varscan2
- FAF1 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1348420541; called by muse, mutect2, varscan2
- FAM135A | c.3733G>A p.E1245K (on ENST00000370479 / NM_001351599.1; = p.E1032K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs759603717; called by muse, mutect2, varscan2
- FAM200B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as rs571879184; called by muse, mutect2, varscan2
- FAM47B | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs779541248; called by muse, mutect2, varscan2
- FAT1 | c.10285G>A p.D3429N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs747735486, COSV71671990; called by muse, mutect2, varscan2
- FBN1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.68); catalogued as rs767893806, COSV57328405; called by muse, mutect2, varscan2
- FBN2 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99328375; called by muse, mutect2, varscan2
- FBXL17 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV99073523; called by muse, mutect2, varscan2
- FCHSD2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as rs1477091005; called by muse, mutect2, varscan2
- FCRL5 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62512895; called by muse, mutect2
- FHOD3 | c.3983C>T p.T1328I (on ENST00000359247 / NM_001281739.3; = p.T1345I on NM_025135.5) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as rs768456654; called by muse, mutect2, varscan2
- FILIP1L | c.1141G>C p.D381H (on ENST00000354552 / NM_182909.3; = p.D141H on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs752275867; called by muse, mutect2
- FMO4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 86/390 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1358907730; called by muse, mutect2, varscan2
- FOXL3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as rs1277083763; called by muse, mutect2, varscan2
- FRMD4B | c.953+5G>A | Splice Region (SNP) | VAF 27/103 reads (26%) | catalogued as rs1446690656; called by muse, mutect2, varscan2
- FUT7 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.449); catalogued as rs774639941; called by muse, mutect2, varscan2
- FXR2 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100007050; called by muse, mutect2, varscan2
- GABRA6 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1489529981; called by muse, mutect2, varscan2
- GAGE10 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as COSV68163704; called by muse, mutect2, varscan2
- GALNT9 | c.1763C>T p.S588L (on ENST00000328957 / NM_001122636.2; = p.S222L on NM_021808.3) | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1429111888, COSV61098668; called by muse, mutect2, varscan2
- GBA3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101545562; called by muse, mutect2, varscan2
- GLI3 | c.4055C>T p.S1352L | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV67886410; called by muse, mutect2, varscan2
- GLI4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60681973; called by muse, mutect2, varscan2
- GMPPB | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 140/447 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1559697205; called by muse, mutect2, varscan2
- GPR171 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56382534; called by muse, mutect2, varscan2
- GRB14 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs754810261; called by muse, mutect2, varscan2
- HECW2 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs149635005; called by muse, mutect2, varscan2
- HERC1 | c.11638C>T p.H3880Y | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746019323, COSV71248494, COSV71250162; called by muse, mutect2, varscan2
- HERC2 | c.11752C>G p.L3918V | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs766759949; called by muse, mutect2, varscan2
- HHIP | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs762754919, COSV99667546; called by muse, mutect2, varscan2
- HOXB5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1453457823, COSV99494329; called by muse, mutect2, varscan2
- HOXB6 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 153/499 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312334, COSV99494440; called by muse, mutect2, varscan2
- HOXC13 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.735); catalogued as COSV54497971; called by muse, mutect2, varscan2
- INMT | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.056); catalogued as rs776680865; called by muse, mutect2, varscan2
- INO80B | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 111/204 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs749472056, COSV51972294; called by muse, mutect2, varscan2
- INTS5 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 83/309 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs777192665, COSV57950956; called by muse, mutect2, varscan2
- INTS9 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV68435146; called by muse, mutect2, varscan2
- IPO11 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 155/388 reads (40%) | catalogued as COSV57583739; called by muse, mutect2, varscan2
- IREB2 | c.2674C>T p.Q892* | Nonsense Mutation (SNP) | VAF 111/393 reads (28%) | catalogued as COSV51926118; called by muse, mutect2, varscan2
- IRX2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as rs747961060; called by muse, mutect2, varscan2
- ISLR2 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs1319948181, COSV62302394; called by muse, mutect2, varscan2
- KALRN | c.1924A>G p.M642V | Missense Mutation (SNP) | VAF 103/388 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99562502; called by muse, mutect2, varscan2
- KAT6A | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1171242735; called by muse, mutect2, varscan2
- KATNIP | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs1279119204, COSV55179304; called by muse, mutect2, varscan2
- KCNA4 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 115/428 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as rs957063987, COSV60254236, COSV60256674; called by muse, mutect2, varscan2
- KCNK12 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as rs1345447230, COSV59947034; called by muse, mutect2, varscan2
- KCNU1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1111125; called by muse, mutect2, varscan2
- KDM6B | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 214/841 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.469); catalogued as rs945572343; called by muse, mutect2, varscan2
- KIAA0100 | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV66496214; called by muse, mutect2
- KIAA2026 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs748673441, COSV52388503, COSV99035492; called by muse, mutect2, varscan2
- KIF16B | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100734747; called by muse, mutect2, varscan2
- KLF4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1438340936; called by muse, mutect2, varscan2
- KLHDC3 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV55065407; called by muse, mutect2, varscan2
- KRTAP6-1 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 272/454 reads (60%) | PolyPhen benign (0.071); catalogued as COSV100228857; called by muse, mutect2, varscan2
- LAMA5 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs1238232872; called by muse, mutect2, varscan2
- LATS2 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV66878288; called by muse, mutect2, varscan2
- LEO1 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | catalogued as COSV55174954, COSV55175672; called by muse, mutect2
- LIPN | c.585G>A p.M195I | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as COSV101356229; called by muse, mutect2, varscan2
- LOXL2 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs749058378, COSV66690888; called by muse, mutect2, varscan2
- LPA | c.3605G>A p.R1202K | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.945); catalogued as COSV60295923, COSV60298364; called by muse, varscan2
- LRP1 | c.12752C>G p.S4251C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV54521260; called by muse, mutect2, varscan2
- LRP5 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV53711433; called by muse, mutect2, varscan2
- LRRC41 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV58440929; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- LYST | c.4315G>C p.D1439H | Missense Mutation (SNP) | VAF 110/545 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs1357145497; called by muse, mutect2, varscan2
- MAMDC2 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs1327072454; called by muse, mutect2, varscan2
- MAST3 | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 114/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs868101301; called by muse, varscan2
- MCL1 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 82/384 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as COSV57191352; called by muse, mutect2, varscan2
- MELK | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53199535; called by muse, mutect2, varscan2
- METTL22 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50837341; called by muse, mutect2
- MFSD13A | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs755447952; called by muse, mutect2, varscan2
- MGST1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 248/603 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as COSV50567097; called by muse, mutect2, varscan2
- MLH1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 104/392 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as CM024457, COSV51617410; called by muse, mutect2, varscan2
- MPHOSPH8 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as rs1213195030; called by muse, varscan2
- MPPED2 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV63900896; called by muse, mutect2, varscan2
- MRGPRX4 | c.947C>A p.S316* | Nonsense Mutation (SNP) | VAF 64/284 reads (23%) | catalogued as COSV58590471; called by muse, mutect2, varscan2
- MUC12 | c.14581C>G p.P4861A (on ENST00000379442; = p.P4718A on NM_001164462.1) | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious, low confidence (0.02); catalogued as rs10249439; called by muse, mutect2, varscan2
- MUC12 | c.15005C>T p.S5002L (on ENST00000379442; = p.S4859L on NM_001164462.1) | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0); catalogued as rs755310682; called by muse, mutect2, varscan2
- MUC6 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs760912439, COSV70134698; called by muse, mutect2, varscan2
- MYH4 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV55117905; called by muse, mutect2, varscan2
- MYO18B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751222865, COSV59126310, COSV59129122; called by muse, mutect2, varscan2
- MYO3A | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1456411630; called by muse, varscan2
- MYO7B | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1019917444, COSV67350749; called by muse, mutect2, varscan2
- NAV1 | c.1355C>G p.S452* | Nonsense Mutation (SNP) | VAF 47/253 reads (19%) | catalogued as COSV55226333; called by muse, varscan2
- NCF4 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs748770662; called by muse, mutect2, varscan2
- NDRG4 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs1285723384, COSV50752177; called by muse, mutect2, varscan2
- NELL1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54246746, COSV54280278; called by muse, mutect2, varscan2
- NFE2L2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67960064; called by muse, mutect2
- NKX2-5 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs866619868; called by muse, mutect2, varscan2
- NKX6-2 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs146723849; called by muse, mutect2, varscan2
- NLE1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761041022; called by muse, mutect2, varscan2
- NLRP11 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100789598, COSV100789614; called by muse, mutect2
- NLRP3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.258); catalogued as COSV100275619, COSV60219647; called by muse, mutect2, varscan2
- NOC3L | c.2238C>G p.F746L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240394333; called by muse, mutect2, varscan2
- NOL10 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV62042936; called by muse, varscan2
- NOTCH3 | c.6109C>T p.H2037Y | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.703); catalogued as rs760895346; called by muse, mutect2, varscan2
- NPTX1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs747838744; called by muse, mutect2, varscan2
- NR1D1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 38/142 reads (27%) | catalogued as COSV99225719; called by muse, mutect2, varscan2
- NSMAF | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV50697649; called by muse, mutect2, varscan2
- NSMCE2 | c.32C>A p.S11* | Nonsense Mutation (SNP) | VAF 147/316 reads (47%) | catalogued as COSV54896749, COSV54898219; called by muse, mutect2, varscan2
- NT5C1A | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV52496864; called by muse, mutect2, varscan2
- NUF2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV54848006; called by muse, mutect2, varscan2
- OBSL1 | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV54703033; called by muse, mutect2, varscan2
- OR10A7 | c.950G>C p.*317Sext*? | Nonstop Mutation (SNP) | VAF 60/132 reads (45%) | catalogued as COSV58278942, COSV58279393; called by muse, mutect2, varscan2
- OR2AJ1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 5/88 reads (6%) | catalogued as COSV59089237; called by muse, mutect2
- OR6P1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58110494; called by muse, mutect2, varscan2
- OR8D1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763059890; called by muse, mutect2, varscan2
- OR8D4 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV58430172, COSV58430600; called by muse, mutect2, varscan2
- OR9G1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 95/801 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs1388827416; called by muse, mutect2
- OSBPL6 | c.1540G>C p.D514H | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV51924527; called by muse, mutect2, varscan2
- OTOF | c.2626G>T p.E876* (on ENST00000272371 / NM_194248.3; = p.E129* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV55520854; called by muse, mutect2, varscan2
- OTOGL | c.5260G>A p.D1754N (on ENST00000547103; = p.D1745N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1429518056; called by muse, mutect2, varscan2
- P3H3 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs1555122756, COSV99300752; called by muse, mutect2, varscan2
- P3H4 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 100/336 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs782321072, COSV58638425; called by muse, mutect2, varscan2
- PAPOLB | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV68202191; called by muse, mutect2, varscan2
- PARP4 | c.4859G>A p.R1620K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV67964404; called by muse, mutect2, varscan2
- PCBP4 | c.659C>T p.S220L (on ENST00000322099 / NM_033010.2; = p.S177L on NM_020418.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100436997, COSV100437031; called by muse, mutect2, varscan2
- PCDH18 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 145/483 reads (30%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.747); catalogued as rs769108724, COSV61266910, COSV61268874; called by muse, mutect2, varscan2
- PCDHGA4 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.474); catalogued as rs750661536; called by muse, mutect2, varscan2
- PCDHGB2 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.122); catalogued as COSV99537365; called by muse, mutect2, varscan2
- PCNX4 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 103/212 reads (49%) | catalogued as rs754019433, COSV100470590; called by muse, mutect2, varscan2
- PCOLCE2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs777136521, COSV99930430; called by muse, mutect2, varscan2
- PDE6B | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV55325179; called by muse, mutect2, varscan2
- PDLIM5 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 106/387 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs1473036920; called by muse, mutect2, varscan2
- PELI2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50715917; called by muse, mutect2, varscan2
- PELI3 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as COSV100291771; called by muse, mutect2, varscan2
- PLD1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs773561636; called by muse, mutect2, varscan2
- PLEKHG1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 217/492 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62049173; called by muse, mutect2, varscan2
- PLEKHJ1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV55557533; called by muse, mutect2, varscan2
- PLEKHM1 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1336172732; called by muse, mutect2, varscan2
- PLEKHM2 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs745963513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLIN2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs926017786; called by muse, mutect2, varscan2
- PLPPR5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.248); catalogued as COSV54175081; called by muse, mutect2, varscan2
- PLXNA4 | c.4729G>A p.D1577N | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762943057; called by muse, mutect2, varscan2
- POLD3 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99737892; called by muse, mutect2, varscan2
- POLE | c.6033G>A p.M2011I | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs754773239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCD | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs782581303; called by muse, mutect2
- PROSER2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs972022903; called by muse, mutect2, varscan2
- PRPF8 | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100518045; called by muse, mutect2, varscan2
- PRTN3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.045); catalogued as rs781190531; called by muse, mutect2, varscan2
- PSD4 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV55528957; called by muse, mutect2, varscan2
- PTPDC1 | c.1886G>A p.R629K (on ENST00000375360 / NM_177995.3; = p.R681K on NM_152422.4) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV56621254; called by muse, mutect2, varscan2
- PTPMT1 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.293); catalogued as rs938906164, COSV58598141; called by muse, mutect2, varscan2
- PTPRD | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV61927126, COSV61970136; called by muse, mutect2, varscan2
- PTPRT | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 166/357 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV61958672; called by muse, mutect2, varscan2
- PTTG2 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs752876023; called by muse, mutect2, varscan2
- PUM1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 129/280 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV57083063; called by muse, mutect2, varscan2
- RAB11FIP1 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.557); catalogued as rs776710257, COSV54764270; called by muse, mutect2, varscan2
- RALGAPA1 | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs760936820; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 72/130 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RASSF7 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1273382500; called by muse, mutect2, varscan2
- RC3H2 | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs1369772175, COSV61802965; called by muse, mutect2, varscan2
- REG3A | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs778024360, COSV59408452; called by muse, mutect2, varscan2
- RFX6 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100263733; called by muse, mutect2, varscan2
- RGL4 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs375293031; called by muse, mutect2, varscan2
- RIIAD1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV51884950, COSV51885528; called by muse, mutect2, varscan2
- RNF169 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 68/241 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs749118015, COSV100213591; called by muse, mutect2, varscan2
- ROCK1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101296591; called by muse, mutect2, varscan2
- RYR1 | c.6083G>C p.R2028P | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV62103723; called by muse, mutect2
- SAMD9 | c.4392C>G p.F1464L | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1460994810, COSV66075827; called by muse, mutect2, varscan2
- SAMHD1 | c.209-1G>A p.X70_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | catalogued as COSV53429928, COSV53431660; called by muse, mutect2, varscan2
- SCN9A | c.4744G>C p.D1582H (on ENST00000303354; = p.D1571H on NM_002977.3) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57624242; called by muse, mutect2, varscan2
- SCNN1B | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs372687977; called by muse, mutect2, varscan2
- SDK1 | c.3444G>A p.M1148I | Missense Mutation (SNP) | VAF 23/540 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV67359641; called by muse, mutect2
- SEC31A | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760483691, COSV52343862; called by muse, mutect2, varscan2
- SEMA5B | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs189074897; called by muse, mutect2, varscan2
- SH2B1 | c.1897+8G>A | Splice Region (SNP) | VAF 64/230 reads (28%) | catalogued as rs1207387393; called by muse, mutect2, varscan2
- SH3GL2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV66056095; called by muse, mutect2, varscan2
- SH3GL2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs760110411, COSV101014250; called by muse, mutect2, varscan2
- SHANK1 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs912954318; called by muse, mutect2, varscan2
- SHC2 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1386932768; called by muse, mutect2
- SHF | c.-49G>A | Splice Region (SNP) | VAF 37/105 reads (35%) | catalogued as rs1198331252; called by muse, mutect2, varscan2
- SLC16A13 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs752412090; called by muse, mutect2
- SLC24A5 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as rs1006909458; called by muse, mutect2, varscan2
- SLC26A4 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs547278884, COSV99706798; called by muse, mutect2, varscan2
- SLC27A1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs371654438; called by muse, mutect2, varscan2
- SLC35E4 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs753658308; called by muse, mutect2, varscan2
- SLC39A1 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1237098899; called by muse, mutect2, varscan2
- SLC39A6 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1476176781; called by muse, mutect2, varscan2
- SLC4A9 | c.2765G>A p.R922Q (on ENST00000507527 / NM_001258428.2; = p.R898Q on NM_031467.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762998447, COSV50195995; called by muse, mutect2, varscan2
- SLC5A12 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54819194; called by muse, mutect2, varscan2
- SLC7A10 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1310144712, COSV53502806; called by muse, mutect2, varscan2
- SMC5 | c.2095G>C p.E699Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100746959; called by muse, mutect2, varscan2
- SMG7 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs550924906; called by muse, mutect2, varscan2
- SNAPC2 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99683978; called by muse, mutect2, varscan2
- SNX17 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs749704686, COSV52007015; called by muse, mutect2, varscan2
- SOX1 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs1437027424; called by muse, mutect2, varscan2
- SOX10 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.239); catalogued as CD023279; called by muse, mutect2, varscan2
- SPATA48 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV51675339; called by muse, mutect2, varscan2
- SPHKAP | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs775866234, COSV60871291, COSV60892119; called by muse, mutect2, varscan2
- SPOCD1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs372711065; called by muse, mutect2, varscan2
- SPRED1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54437401, COSV54439454; called by muse, mutect2, varscan2
- SPTAN1 | c.5938C>T p.Q1980* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV63985291, COSV63987027; called by muse, mutect2, varscan2
- SRRM2 | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs944139652, COSV57076799; called by muse, mutect2, varscan2
- SRRM2 | c.8224C>T p.R2742W | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs746760304, COSV51939998; called by muse, mutect2, varscan2
- SSU72P8 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1396784218, COSV66361059; called by muse, mutect2, varscan2
- STK11IP | c.387C>G p.I129M | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1559176796, COSV55247539; called by muse, mutect2, varscan2
- SULF1 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs768438365, COSV52673919; called by muse, mutect2, varscan2
- SYNE1 | c.7238-1G>C p.X2413_splice (on ENST00000367255 / NM_182961.4; = p.X2420_splice on NM_033071.3) | Splice Site (SNP) | VAF 29/45 reads (64%) | catalogued as COSV99555128; called by muse, mutect2, varscan2
- SYNE2 | c.17065C>T p.R5689W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs540618925; called by muse, mutect2, varscan2
- SYT16 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.129); catalogued as COSV70857801; called by muse, mutect2, varscan2
- SYTL2 | c.2434C>G p.L812V (on ENST00000528231 / NM_001162951.2; = p.L788V on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); catalogued as rs1472836026; called by muse, mutect2, varscan2
- TAB3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.81); catalogued as COSV99916802; called by muse, mutect2, varscan2
- TCF7 | c.918+3G>A | Splice Region (SNP) | VAF 52/104 reads (50%) | catalogued as rs62379393; called by muse, varscan2
- THBS4 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV63471729; called by muse, mutect2, varscan2
- THSD7B | c.3857G>A p.R1286Q (on ENST00000272643; = p.R1284Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745747984; called by muse, mutect2, varscan2
- TJP2 | c.2492C>T p.T831M | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as rs778708131; called by muse, mutect2, varscan2
- TLR4 | c.1934C>T p.S645F (on ENST00000355622 / NM_138554.5; = p.S605F on NM_003266.4) | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100842621; called by muse, mutect2, varscan2
- TMBIM4 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs755915391; called by muse, mutect2, varscan2
- TMEM102 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV53439017; called by muse, mutect2, varscan2
- TMEM250 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs372684658; called by muse, mutect2, varscan2
- TNFRSF21 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs143637698; called by muse, mutect2, varscan2
- TOMM5 | c.48G>C p.M16I | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV58375502; called by muse, mutect2
- TPBGL | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1379537891, COSV73206721; called by muse, mutect2, varscan2
- TPR | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs768275946; called by muse, mutect2, varscan2
- TRIM43 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV55529632; called by muse, mutect2, varscan2
- TRPC7 | c.2369G>C p.R790T | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61452145; called by muse, mutect2, varscan2
- TSC1 | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100051233, COSV53769300; called by muse, mutect2, varscan2
- TTC21A | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1205695059, COSV57183197; called by muse, mutect2, varscan2
- TTC3 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.622); catalogued as rs771969912; called by muse, mutect2, varscan2
- TTN | c.24613G>A p.D8205N (on ENST00000591111; = p.D7278N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | PolyPhen possibly damaging (0.885); catalogued as rs199619070; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UACA | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV100537695; called by muse, mutect2, varscan2
- UGGT1 | c.4384C>T p.Q1462* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as COSV52136640; called by muse, mutect2, varscan2
- USP47 | c.2905G>A p.D969N (on ENST00000399455 / NM_001372095.1; = p.D881N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV60465668; called by muse, varscan2
- WDR72 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100854073; called by muse, mutect2, varscan2
- WEE2 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV66878506; called by muse, mutect2, varscan2
- WNT10B | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs775256500, COSV56405088; called by muse, mutect2, varscan2
- WWC3 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs376544629, COSV66501512; called by muse, mutect2, varscan2
- XIRP2 | c.2473C>T p.Q825* (on ENST00000628543; = p.Q1000* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | catalogued as COSV54701163; called by muse, mutect2, varscan2
- YME1L1 | c.1036G>A p.E346K (on ENST00000326799 / NM_139312.3; = p.E289K on NM_014263.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100464302; called by muse, mutect2, varscan2
- ZBED8 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as COSV68825188; called by muse, varscan2
- ZEB2 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 55/120 reads (46%) | catalogued as COSV57965389; called by muse, mutect2, varscan2
- ZFP91 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); catalogued as rs764585837, COSV100284254; called by muse, mutect2, varscan2
- ZMYM4 | c.2505G>A p.M835I | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV58913630; called by muse, mutect2, varscan2
- ZNF212 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1258495254; called by muse, mutect2, varscan2
- ZNF213 | c.1252G>C p.D418H | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as rs748347640; called by muse, mutect2, varscan2
- ZNF221 | c.1518C>G p.F506L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs1384346404; called by muse, mutect2, varscan2
- ZNF433 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV61398581; called by muse, mutect2, varscan2
- ZNF479 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV58639288; called by muse, mutect2, varscan2
- ZNF668 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 142/282 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs779961869; called by muse, mutect2, varscan2
- ZNF763 | c.775C>G p.Q259E (on ENST00000358987 / NM_001367172.2; = p.Q262E on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/388 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100676137; called by muse, mutect2, varscan2
- ZNF768 | c.86G>C p.R29T | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53224773; called by muse, mutect2, varscan2
- ZNF814 | c.2417G>C p.G806A | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748797059; called by muse, mutect2, varscan2
- ZZEF1 | c.3244G>C p.E1082Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV101068263; called by muse, mutect2, varscan2
- ABCA2 | c.6990C>G p.F2330L (on ENST00000614293; = p.F2300L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCA5 | c.4909G>A p.E1637K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ABHD2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABLIM1 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACO2 | c.1296+3G>C | Splice Region (SNP) | VAF 202/448 reads (45%) | called by muse, mutect2, varscan2
- ACRV1 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 79/265 reads (30%) | called by muse, mutect2, varscan2
- ADAM17 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ADAMTS1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADCY10 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADGRB2 | c.1221G>C p.Q407H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ADGRE5 | c.1076-1G>C p.X359_splice (on ENST00000242786 / NM_078481.4; = p.X266_splice on NM_001784.5) | Splice Site (SNP) | VAF 89/363 reads (25%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4268C>T p.S1423L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AFDN | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 62/111 reads (56%) | called by muse, mutect2, varscan2
- AGO3 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 130/311 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AGTPBP1 | c.3547G>A p.E1183K (on ENST00000357081 / NM_001330701.2; = p.E1143K on NM_015239.2) | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- AGXT2 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- AHNAK | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- AL353743.4 | n.507G>A | Splice Region (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- AMBN | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 148/526 reads (28%) | called by muse, mutect2, varscan2
- AMBN | c.793G>C p.V265L | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMBRA1 | c.3480G>A p.M1160I (on ENST00000458649 / NM_001367468.1; = p.M1070I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- AMER2 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMOTL2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANGEL2 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ANK3 | c.7409C>T p.S2470L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD13B | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ANKRD26 | c.2725G>C p.D909H | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ANO3 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ANO7 | c.2377C>T p.R793C (on ENST00000274979; = p.R739C on NM_001370694.2) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ANO8 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AP3B2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP42 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGAP45 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 85/368 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.2887+3G>T | Splice Region (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2
- ARHGEF2 | c.2614G>A p.E872K (on ENST00000361247 / NM_001162383.2; = p.E844K on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ARHGEF28 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ARMCX5 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARMH1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- ARPC4 | c.272T>A p.M91K | Missense Mutation (SNP) | VAF 157/664 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ART1 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 118/385 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASAH1 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ASAP2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASB14 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ASCC2 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ASPHD2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASPRV1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ASTN1 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATG14 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 100/218 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ATP10A | c.4040C>T p.S1347F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP13A4 | c.2670C>T p.I890= | Splice Region (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- ATP2C2 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ATP5MF | c.255C>A p.L85= | Splice Region (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- ATP8B1 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AUTS2 | c.3125G>C p.R1042T | Missense Mutation (SNP) | VAF 248/383 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- B4GALNT3 | c.1561delinsCTA p.E521Lfs*19 | Frame Shift Ins (INS) | VAF 56/226 reads (25%) | called by pindel, varscan2*
- B4GALNT4 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- BCORL1 | c.4990C>A p.Q1664K | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- BECN1 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BECN1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2
- BEND5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BICRAL | c.2705G>A p.R902K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP15 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C1orf127 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- C2CD5 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf62 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C4orf19 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- C6 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- CABS1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CACNA1A | c.6860G>T p.R2287L | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CACNA1C | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CACNA1D | c.2269G>A p.D757N (on ENST00000350061 / NM_001128840.3; = p.D777N on NM_000720.4) | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CACNA2D3 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CAMK2B | c.70dup p.A24Gfs*16 | Frame Shift Ins (INS) | VAF 55/156 reads (35%) | called by mutect2, varscan2
- CAMKK1 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.3179C>G p.S1060C | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CAMSAP3 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 79/446 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CAPN12 | c.1130-1G>A p.X377_splice | Splice Site (SNP) | VAF 84/182 reads (46%) | called by muse, mutect2, varscan2
- CATSPERB | c.3350G>C p.*1117Sext*23 | Nonstop Mutation (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.114G>C p.K38N | Missense Mutation (SNP) | VAF 171/345 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CBX3 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2
- CCDC110 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CCDC150 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC167 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CCDC168 | c.16922C>T p.S5641L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC168 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CCDC88A | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CD101 | c.2240G>C p.R747T | Missense Mutation (SNP) | VAF 83/155 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CD46 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CDC42BPA | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH16 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 91/193 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CDH20 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CDX1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CEP350 | c.7085C>T p.S2362F | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CEP83 | c.1627C>T p.H543Y | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- CHADL | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- CHD1 | c.4067C>T p.S1356F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CLK3 | c.1540G>A p.E514K (on ENST00000395066 / NM_001130028.1; = p.E366K on NM_003992.4) | Missense Mutation (SNP) | VAF 106/351 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- CLPB | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP4 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL16A1 | c.1800G>C p.E600D | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- COL17A1 | c.1222+5G>A | Splice Region (SNP) | VAF 116/235 reads (49%) | called by muse, mutect2, varscan2
- COL18A1 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- COL27A1 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL6A5 | c.3844C>G p.L1282V | Missense Mutation (SNP) | VAF 83/266 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COPA | c.1144-1G>C p.X382_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- COPZ1 | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 86/172 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CPSF7 | c.466G>A p.D156N (on ENST00000394888 / NM_001136040.4; = p.D199N on NM_024811.4) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREB3L4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 143/612 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBL2 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CRYAB | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CSNK2A3 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CTDSP1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CUL7 | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CWC25 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CWF19L1 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 158/316 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CYP26C1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- DCAF15 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DCST2 | c.2173C>T p.Q725* | Nonsense Mutation (SNP) | VAF 23/116 reads (20%) | called by muse, mutect2, varscan2
- DGKB | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRSX | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- DHX35 | c.1956-10_1956-8delinsTA | Splice Region (DEL) | VAF 52/142 reads (37%) | called by pindel, varscan2*
- DHX36 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by mutect2, varscan2
- DIP2C | c.2478G>C p.R826S | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DISP3 | c.-3-7C>T | Splice Region (SNP) | VAF 96/194 reads (49%) | called by muse, mutect2, varscan2
- DNAH3 | c.9441C>G p.F3147L | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DNAH5 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH5 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DNAH7 | c.8911G>A p.D2971N | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOT1L | c.3429C>G p.I1143M | Missense Mutation (SNP) | VAF 97/463 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRP2 | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DTX3L | c.1476G>C p.L492F | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYRK2 | c.1392C>G p.Y464* (on ENST00000344096 / NM_006482.3; = p.Y391* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 65/113 reads (58%) | called by muse, mutect2, varscan2
- ECT2 | c.2209C>T p.Q737* (on ENST00000392692 / NM_001349098.2; = p.Q706* on NM_018098.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 50/284 reads (18%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF3A | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 99/227 reads (44%) | called by muse, mutect2, varscan2
- EIF4G1 | c.2869C>T p.Q957* (on ENST00000346169 / NM_198241.3; = p.Q762* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 76/224 reads (34%) | called by muse, mutect2, varscan2
- ELAPOR1 | c.2952G>T p.K984N | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPOP | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6 | c.3496G>A p.E1166K | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ERCC6L | c.2926G>C p.E976Q | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ESPNL | c.2247G>T p.W749C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESRRG | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ETV5 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 53/166 reads (32%) | called by muse, mutect2, varscan2
- FADD | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FAM111A | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 116/395 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM118B | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM122C | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 191/464 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- FAM126A | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FAM135A | c.1259-8G>A | Splice Region (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- FAM135B | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM149A | c.2036C>T p.S679F (on ENST00000356371 / NM_001367768.2; = p.S388F on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM170B | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, varscan2
- FAM53B | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FAM71E2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAT4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FBRSL1 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- FBXL3 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 100/244 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- FBXO33 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FGD5 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL2 | c.1904C>T p.S635F | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- FNIP1 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- FOXE1 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FOXRED1 | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- FREM1 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD5 | c.1274C>T p.S425L | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- FZR1 | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GAL3ST3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- GDA | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 96/274 reads (35%) | called by muse, mutect2, varscan2
- GMPPB | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 118/343 reads (34%) | called by muse, mutect2, varscan2
- GNE | c.1832C>T p.S611F (on ENST00000396594 / NM_001128227.3; = p.S580F on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GNPNAT1 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GOLGA3 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GOLGB1 | c.1221A>T p.Q407H | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by mutect2, varscan2
- GP1BA | c.1891C>G p.L631V | Missense Mutation (SNP) | VAF 79/247 reads (32%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- GPC3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GPR37 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM2 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GSPT1 | c.694G>T p.E232* (on ENST00000420576 / NM_001130007.2; = p.E370* on NM_002094.4) | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- GSPT2 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 76/142 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GTF2IRD1 | c.2692C>T p.P898S (on ENST00000265755 / NM_016328.3; = p.P883S on NM_005685.4) | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- GTF3C4 | c.1564G>C p.A522P | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- HAP1 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HAUS5 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- HEATR1 | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR5A | c.3092C>T p.S1031F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECTD1 | c.3689C>T p.S1230L | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HERC1 | c.3962C>T p.S1321L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HERC1 | c.2423G>A p.G808E | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- HHEX | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HMCN1 | c.13507G>C p.D4503H | Missense Mutation (SNP) | VAF 69/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGB1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- HNRNPU | c.1585G>C p.D529H (on ENST00000283179; = p.D591H on NM_004501.3) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- HNRNPU | c.1501-1G>C p.X501_splice (on ENST00000283179; = p.X563_splice on NM_004501.3) | Splice Site (SNP) | VAF 20/156 reads (13%) | called by muse, varscan2
- HOMEZ | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HOMEZ | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- HRC | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, varscan2
- HSCB | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- HTR3D | c.1240C>G p.Q414E (on ENST00000382489 / NM_001163646.2; = p.Q239E on NM_182537.3) | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- HTT | c.3995C>G p.S1332C | Missense Mutation (SNP) | VAF 201/661 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- HUWE1 | c.9705G>C p.E3235D | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HYLS1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IFI16 | c.1696G>A p.E566K (on ENST00000295809 / NM_001364867.2; = p.E510K on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- IFIT2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- IFIT2 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, varscan2
- IFNGR2 | c.821G>C p.R274T | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- IFNK | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 180/522 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.429); called by muse, varscan2
- IFNK | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 136/466 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, varscan2
- IFT80 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- IGF2R | c.7061C>T p.S2354L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGFBP6 | c.600+3G>A | Splice Region (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- IGKC | c.324G>C p.*108Yext*59 | Nonstop Mutation (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- ILRUN | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- INO80D | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- INTS1 | c.3985G>C p.E1329Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ITFG1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITFG2 | c.592_594delinsTA p.L198* | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | called by pindel, varscan2*
- ITGB2 | c.1327G>C p.E443Q (on ENST00000302347; = p.E419Q on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGB8 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 114/380 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH6 | c.3898G>A p.V1300I | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ITLN1 | c.59-1G>C p.X20_splice | Splice Site (SNP) | VAF 144/287 reads (50%) | called by muse, mutect2, varscan2
- IWS1 | c.2221C>T p.L741F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated, low confidence (0.87); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- JPH4 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANSL2 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 74/179 reads (41%) | called by muse, mutect2, varscan2
- KAT2A | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK4 | c.1004C>G p.S335W | Missense Mutation (SNP) | VAF 182/521 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KCNMA1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KDM5B | c.3317G>A p.R1106K | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6B | c.1400C>A p.S467* | Nonsense Mutation (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- KIF13A | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF13B | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KIRREL3 | c.1107G>T p.M369I | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KLHL23 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KLK12 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KMT2C | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KMT5A | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KNDC1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- LAMA1 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LAMA5 | c.3422C>G p.S1141C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- LAMB3 | c.800C>A p.A267E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, varscan2
- LAMB3 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.116); called by muse, varscan2
- LEMD2 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIG4 | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- LINC02203 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 6/7 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by mutect2, varscan2
- LINGO2 | c.1751G>C p.R584T | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LOXHD1 | c.5647G>C p.E1883Q (on ENST00000642948; = p.E1821Q on NM_144612.7) | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LRBA | c.5167G>C p.D1723H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1 | c.5446G>A p.D1816N | Missense Mutation (SNP) | VAF 85/155 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LRRK1 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- MAGEE1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- MAGEL2 | c.2765G>A p.W922* | Nonsense Mutation (SNP) | VAF 90/316 reads (28%) | called by muse, mutect2, varscan2
- MAGI1 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MAGI2 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2
- MAP4K3 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBLAC1 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 161/254 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCMBP | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MESP1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MEST | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- MORC1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORC3 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPPED1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 102/292 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MPPED2 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MROH2B | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MS4A3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTREX | c.2662C>G p.L888V | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MUC1 | c.3384C>A p.F1128L (on ENST00000611571 / NM_001371720.1; = p.F139L on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MUC1 | c.3191C>T p.S1064F (on ENST00000611571 / NM_001371720.1; = p.S75F on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC19 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MUC19 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- MUC5B | c.14267C>T p.S4756F | Missense Mutation (SNP) | VAF 156/488 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYCBP2 | c.8209G>C p.D2737H (on ENST00000357337; = p.D2775H on NM_015057.5) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYH14 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- MYH2 | c.5413G>T p.E1805* | Nonsense Mutation (SNP) | VAF 75/230 reads (33%) | called by muse, mutect2, varscan2
- MYO10 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- MYO1B | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MYO1H | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- MYO7A | c.2368-1G>A p.X790_splice | Splice Site (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- MYORG | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- NAGS | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- NAT16 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NAV1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, varscan2
- NCF2 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCKAP5 | c.4278G>C p.Q1426H | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NCKAP5 | c.3739G>A p.D1247N | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- NDST3 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.211); called by muse, mutect2
- NDUFAF8 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- NECAP1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 139/322 reads (43%) | called by muse, mutect2, varscan2
- NELFB | c.140C>G p.S47W | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NEO1 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NES | c.2847G>C p.Q949H | Missense Mutation (SNP) | VAF 249/1047 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NEUROD2 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- NEXMIF | c.3244C>T p.Q1082* | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | called by muse, mutect2, varscan2
- NFKB2 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 72/88 reads (82%) | called by muse, mutect2, varscan2
- NISCH | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NMT2 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NOP2 | c.668dup p.A224Cfs*29 (on ENST00000322166 / NM_001258308.2; = p.A220Cfs*29 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 79/226 reads (35%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.4449C>A p.F1483L | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPHP3 | c.3329+3G>A | Splice Region (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- NR1I2 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- NR2C2AP | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR4A1 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 181/380 reads (48%) | called by muse, mutect2, varscan2
- NRIP1 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- NSUN4 | c.598C>G p.L200V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NUP214 | c.1477G>C p.A493P | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP42 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NWD2 | c.4069G>A p.E1357K | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- OBSCN | c.18919G>A p.E6307K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OR10Z1 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 78/183 reads (43%) | called by muse, mutect2, varscan2
- OR13C2 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR2A25 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR2B6 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- OR2T34 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, varscan2
- OR52E5 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6S1 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8G3P | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OSBPL8 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- OTOP3 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 108/307 reads (35%) | called by muse, mutect2, varscan2
- OTUD7A | c.2116G>C p.E706Q (on ENST00000307050 / NM_001382637.1; = p.E699Q on NM_130901.3) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.277); called by muse, mutect2
- OVGP1 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PACS1 | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- PAN3 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PARP9 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PATL1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PATL1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDH12 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PCDHA3 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PCDHAC2 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGA2 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.078); called by muse, varscan2
- PCNT | c.9545C>A p.S3182Y | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PDCD7 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDE2A | c.757-3C>T | Splice Region (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- PDE3A | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDE3B | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 68/218 reads (31%) | called by muse, mutect2, varscan2
- PDILT | c.1052C>G p.S351* | Nonsense Mutation (SNP) | VAF 69/155 reads (45%) | called by muse, mutect2, varscan2
- PDK2 | c.763-1G>A p.X255_splice | Splice Site (SNP) | VAF 76/235 reads (32%) | called by muse, mutect2, varscan2
- PDK4 | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 110/164 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PEAK3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PER2 | c.414G>C p.L138F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX2 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PGBD1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHF19 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PHF20 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PHLDB1 | c.2274G>C p.E758D | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- PIK3R6 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PIM3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PIP5K1C | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PITX3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PLA2G7 | c.81A>G p.I27M | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLB1 | c.2327G>A p.G776E | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB3 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PLCD3 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PLEKHA5 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PLEKHB2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLEKHH3 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 77/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHM2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PLK5 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 126/602 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNC1 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PODNL1 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 110/454 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- POGZ | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 115/493 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- POLA1 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- POLQ | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 122/408 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PPA1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- PPARGC1B | c.1872C>G p.I624M | Missense Mutation (SNP) | VAF 120/255 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PPP1R26 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PRDM13 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PRKDC | c.8795C>T p.S2932L | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRPF40A | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- PRPF40B | c.2135C>G p.S712* (on ENST00000380281; = p.S699* on NM_012272.3) | Nonsense Mutation (SNP) | VAF 168/344 reads (49%) | called by muse, mutect2, varscan2
- PSD | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PTGER3 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTK2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- PTPRB | c.3740G>C p.G1247A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTPRF | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PTPRN2 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTTG2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 98/420 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- RAB26 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RAB8B | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- RABL6 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAI14 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RASA1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RASAL3 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBBP6 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- RBM25 | c.1468-5C>G | Splice Region (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- RBM33 | c.2761C>T p.Q921* | Nonsense Mutation (SNP) | VAF 101/321 reads (31%) | called by muse, mutect2, varscan2
- RBM4B | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2
- RBMX | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RDH11 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- RESF1 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RET | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
1,900 further variants in this file (188 protein-altering or splice-affecting, 384 silent, 1,328 other) are not listed here.
